Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A87W, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A87W-01A (Primary Tumor).

Accession:
Specimen Date/Time:

DIAGNOSIS

(A) LEFT EYE, ENUCLEATION:

CHOROIDAL MELANOMA, SPINDLE CELL TYPE, 13 mm base
TUMOR INVADES MAJORITY OF SCLERA IN PERIVASCULAR PATTERN
Extraocular tumor is not identified.
Vortex veins and optic nerve, free of tumor

(> 90%)

ICD-O 3
Melanoma, spindle cell NOS 8722/3
Site: ④ Choroid C69.3
JN 1/16/14

GROSS DESCRIPTION

(A) LEFT GLOBE – An intact enucleation specimen of the left globe (22 x 22 x 23 mm) has an attached optic nerve (9 mm i length). The anterior chamber is formed by a blue-gray iris (10 x 11 mm) surrounding a round 6 mm pupil. Overall, the exte eye and sclera are unremarkable. A shadow is present 12 mm from the limbus from 2 to 4 o'clock nearing the optic nerve (1 cm base on cut section corresponding to a brown-tan tumor in the choroid region with a 5 mm height). The ciliary body is uninvolved. The underlying sclera remains intact.

SECTION CODE: A1-A4, region of vortex veins (superior nasal, superior temporal, inferior temporal, inferior nasal); pupil-optic nerve section; A6, A7, calottes (A7 harvest); A8, optic nerve margin.

CLINICAL HISTORY

Uveal melanoma

SNOMED CODES

T-AA000, M-87203

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not

Entire report and diagnosis completed by:

-----END OF REPORT-----

Discrepancy		☒
HI/AA Discrepancy		☒
Qual/Type/Discrepancy Primary Node		☒
Case (Source)	MANAGED	DISQUALIFIED

Source: NCI Genomic Data Commons file 712d15c5-6ef3-4d59-b13d-82b5f66d93ca (TCGA-WC-A87W.49A74B5C-B59F-414D-B578-45A843529582.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).